Somatic mutation profile of tumor specimen C3N-00665-01 (aliquot CPT0093360009) from CPTAC case C3N-00665, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.9 years (24,055 days).
Specimen C3N-00665-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81e1d2a3-0886-492d-8590-5b149bfc50a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00665-31 (Blood Derived Normal), aliquot CPT0093440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69865c68-4616-40f8-b765-9ece5ffbb9f9

The open-access MAF lists 81 somatic variants for this specimen: 49 protein-altering or splice-affecting, 17 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 17, Intron 5, RNA 3, Frame Shift Del 3, 5'UTR 3, Nonsense Mutation 2, 3'Flank 2, 3'UTR 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IMPG1 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 98/322 reads (30%) | catalogued as rs367576664, CM138541; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MECOM | c.2542C>T p.R848* (on ENST00000468789 / NM_001105078.4; = p.R1036* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 89/291 reads (31%) | catalogued as rs1560118923, COSV52968817; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3665del p.P1222Lfs*2 | Frame Shift Del (DEL) | VAF 193/488 reads (40%) | catalogued as rs867391752; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS20 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs776875165, COSV67135306; called by muse, mutect2, varscan2
- AMDHD1 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57138687; called by muse, mutect2, varscan2
- APCDD1L | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs151131553; called by muse, mutect2, varscan2
- ATP4A | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.141); catalogued as rs750910096, COSV52869298; called by muse, mutect2, varscan2
- CARMIL2 | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1306909529, COSV54665567; called by muse, varscan2
- CFHR5 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748127696, COSV56827976; called by muse, mutect2
- DNAH7 | c.7454G>A p.R2485H | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs766897304, COSV56773922; called by muse, mutect2, varscan2
- DOCK5 | c.4221G>T p.K1407N | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.409); catalogued as COSV52410760; called by muse, mutect2, varscan2
- FHOD1 | c.1696G>T p.G566W | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as COSV99264635; called by muse, mutect2, varscan2
- GALNT7 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 177/598 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99396839; called by muse, mutect2, varscan2
- IGHD | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 152/600 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs555318211; called by muse, mutect2, varscan2
- IGKV1D-16 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 207/744 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs375652808; called by muse, mutect2, varscan2
- IRAG2 | c.3815G>A p.R1272K (on ENST00000636465; = p.R317K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs758245637, COSV57232131; called by muse, mutect2, varscan2
- LAMB2 | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 235/832 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs139670781, COSV59730878; called by muse, mutect2, varscan2
- LRRC14B | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as rs368280607; called by muse, mutect2, varscan2
- MAB21L4 | c.1145G>A p.R382H (on ENST00000388934 / NM_001085437.3; = p.R214H on NM_024861.4) | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs368850189; called by muse, mutect2, varscan2
- MAP3K4 | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100815799; called by muse, mutect2, varscan2
- MAST3 | c.2804del p.S935Cfs*90 | Frame Shift Del (DEL) | VAF 149/569 reads (26%) | catalogued as COSV53229084; called by mutect2, pindel, varscan2
- MXRA5 | c.8015C>T p.T2672M | Missense Mutation (SNP) | VAF 141/410 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774852439, COSV54228915; called by muse, mutect2, varscan2
- NCAPG2 | c.645A>G p.I215M | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.046); catalogued as rs775571563; called by muse, mutect2, varscan2
- NCOA7 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.459); catalogued as rs1410432800; called by muse, mutect2, varscan2
- NOP2 | c.2375G>A p.R792H (on ENST00000322166 / NM_001258308.2; = p.R788H on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/480 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as rs371243135; called by muse, mutect2, varscan2
- NTN4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763585270; called by muse, mutect2, varscan2
- OR2G3 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs773666927, COSV60681842; called by muse, mutect2, varscan2
- PIK3R6 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs377023801; called by muse, mutect2, varscan2
- POLR3B | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 97/388 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1043014755, COSV99943811; called by muse, mutect2, varscan2
- PRSS1 | c.40+1G>A p.X14_splice | Splice Site (SNP) | VAF 153/924 reads (17%) | catalogued as rs149125789; called by muse, varscan2
- PTEN | c.356T>G p.V119G | Missense Mutation (SNP) | VAF 222/535 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1554898113, COSV64310505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RINT1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 94/577 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs770101080, COSV57557811; called by muse, mutect2, varscan2
- SBNO1 | c.1214T>C p.I405T (on ENST00000420886; = p.I404T on NM_018183.5) | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV57346275; called by muse, mutect2, varscan2
- SH2B3 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); catalogued as rs1263604332; called by muse, mutect2, varscan2
- SULT1B1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs150406987; called by muse, mutect2, varscan2
- ZNF768 | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 85/291 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1332820509, COSV100776264; called by muse, mutect2, varscan2
- ZSCAN10 | c.2140C>T p.R714C (on ENST00000252463; = p.R769C on NM_032805.3) | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52970826; called by muse, mutect2, varscan2
- ACAP3 | c.1020C>A p.S340R | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADAMTS12 | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BRWD3 | c.123G>A p.L41= | Splice Region (SNP) | VAF 59/207 reads (29%) | called by muse, mutect2, varscan2
- CES1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 201/1039 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL14A1 | c.3208A>G p.T1070A | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPHX4 | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- HMCN1 | c.7542C>G p.H2514Q | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MRM1 | c.221T>A p.L74H | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- NPIPA7 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C12 | c.400A>T p.M134L | Missense Mutation (SNP) | VAF 115/394 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- OR4C16 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- YLPM1 | c.5146_5147del p.H1716* | Frame Shift Del (DEL) | VAF 70/352 reads (20%) | called by pindel, varscan2
- ADAMTS13 | c.2724C>T p.C908= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs145728650, CM066728; called by muse, mutect2, varscan2
- APPL2 | c.246A>G p.V82= | Silent (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- C19orf67 | c.66C>T p.D22= | Silent (SNP) | VAF 160/554 reads (29%) | called by muse, mutect2, varscan2
- CGREF1 | c.705C>T p.A235= | Silent (SNP) | VAF 76/339 reads (22%) | catalogued as rs757150664; called by muse, varscan2
- FLG2 | c.6858A>G p.P2286= | Silent (SNP) | VAF 167/585 reads (29%) | called by muse, mutect2, varscan2
- IRS1 | c.1581G>A p.S527= | Silent (SNP) | VAF 96/307 reads (31%) | catalogued as rs760830492; called by muse, mutect2, varscan2
- ITGAX | c.291G>A p.A97= | Silent (SNP) | VAF 90/335 reads (27%) | catalogued as rs371786173; called by muse, mutect2, varscan2
- MAST1 | c.252G>A p.A84= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs778059086, COSV52246702; called by muse, mutect2, varscan2
- NCKAP5 | c.5157C>T p.D1719= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as COSV58462366; called by muse, mutect2, varscan2
- OPLAH | c.3249G>A p.S1083= | Silent (SNP) | VAF 12/370 reads (3%) | called by muse, mutect2
- OR10X1 | c.306G>A p.L102= | Silent (SNP) | VAF 116/406 reads (29%) | catalogued as rs1444059725, COSV63767616; called by muse, mutect2, varscan2
- PCDHA6 | c.1683C>T p.N561= | Silent (SNP) | VAF 241/961 reads (25%) | catalogued as rs1293917446, COSV65348083; called by muse, mutect2, varscan2
- PRR14L | c.2469A>G p.K823= | Silent (SNP) | VAF 123/363 reads (34%) | called by muse, mutect2, varscan2
- TMEM185A | c.759G>A p.S253= | Silent (SNP) | VAF 74/699 reads (11%) | catalogued as rs1159514130; called by muse, mutect2, varscan2
- VWC2 | c.531G>A p.P177= | Silent (SNP) | VAF 105/621 reads (17%) | catalogued as rs528790694, COSV61491001; called by muse, mutect2, varscan2
- WIZ | c.885G>A p.E295= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs1405626554; called by muse, mutect2, varscan2
- ZFR2 | c.1767C>T p.D589= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs550704725; called by muse, mutect2, varscan2
- CHAC1 | c.-26C>T | 5'UTR (SNP) | VAF 61/249 reads (24%) | catalogued as rs755645505; called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1531C>G | RNA (SNP) | VAF 42/149 reads (28%) | called by muse, mutect2, varscan2
- DOC2A | c.342+39C>T | Intron (SNP) | VAF 127/415 reads (31%) | catalogued as rs745348941; called by muse, mutect2, varscan2
- HARS1 | chr5:140673417 G>A | 3'Flank (SNP) | VAF 169/582 reads (29%) | called by muse, mutect2, varscan2
- INTS2 | c.-43C>G | 5'UTR (SNP) | VAF 89/337 reads (26%) | catalogued as COSV99248306; called by muse, mutect2, varscan2
- LAIR1 | c.-10G>A | 5'UTR (SNP) | VAF 80/241 reads (33%) | called by muse, mutect2, varscan2
- MED14 | c.*2189C>T | 3'UTR (SNP) | VAF 46/212 reads (22%) | called by muse, mutect2, varscan2
- MRPL49 | c.78+33G>A | Intron (SNP) | VAF 54/147 reads (37%) | catalogued as rs1160306639; called by muse, mutect2, varscan2
- MUC19 | chr12:40545967 G>A | 3'Flank (SNP) | VAF 38/158 reads (24%) | called by muse, mutect2, varscan2
- NBPF22P | n.379C>T | RNA (SNP) | VAF 238/728 reads (33%) | catalogued as rs531869928; called by muse, mutect2, varscan2
- OR2L1P | n.879C>T | RNA (SNP) | VAF 98/338 reads (29%) | catalogued as rs757490859; called by muse, varscan2
- PPP1R14A | c.*29C>T | 3'UTR (SNP) | VAF 17/56 reads (30%) | catalogued as rs769191689; called by muse, mutect2, varscan2
- PRPF4B | c.2581+205C>T | Intron (SNP) | VAF 136/488 reads (28%) | called by muse, mutect2, varscan2
- TMEM218 | c.111-199A>G | Intron (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- WRAP53 | c.955+138G>A | Intron (SNP) | VAF 119/370 reads (32%) | catalogued as rs781593838; called by muse, mutect2, varscan2
